FM case AD15963 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/e13b8c69-0ad1-4424-b06e-357eb23e0d28

Female, 33.2 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the cervix uteri; primary biopsied or resected from the cervix uteri. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
